Gene-level copy-number profile of tumor specimen TCGA-A2-A0T7-01A from TCGA case TCGA-A2-A0T7, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.4 years (18,756 days).
Specimen TCGA-A2-A0T7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.1dafc3c4-349e-4af4-871c-566f44080b09.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0T7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/45c6d015-aeb2-4d36-806b-0e7e2464f6d7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 22,666; copy number 2: 30,622; copy number 3: 3,770; copy number 4: 994; copy number 5: 69; copy number 6: 1,694.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0T7-01A-21D-A087-01): tumor purity 0.49, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,763 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,809,574–39,969,968, 69 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr1:154,104,521–156,456,763, 132 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr8:43,018,424–145,066,685, 1,562 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 22,666. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
